Somatic mutation profile of tumor specimen TCGA-AB-2925-03A (aliquot TCGA-AB-2925-03A-01W-0732-08) from TCGA case TCGA-AB-2925, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.1 years (20,850 days).
Specimen TCGA-AB-2925-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d9126d4-f879-456e-bff4-e2e13c293809.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2925-11A (Solid Tissue Normal), aliquot TCGA-AB-2925-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/438dd482-9563-4207-b7c4-6f7c10b42f17

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Frame Shift Ins 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CFHR2 | c.87C>G p.N29K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66380580; called by muse, mutect2, varscan2
- CSMD1 | c.4401C>A p.N1467K (on ENST00000520002; = p.N1466K on NM_033225.6) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59288288; called by muse, mutect2, varscan2
- GATA2 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62003278; called by muse, mutect2, varscan2
- GDF5 | c.205dup p.A69Gfs*25 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | catalogued as rs753691079; called by mutect2, varscan2
- GRM3 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.55); catalogued as COSV64467861; called by muse, mutect2, varscan2
- HECW1 | c.4754C>T p.S1585L | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs367929468; called by muse, mutect2, varscan2
- KPRP | c.1737T>G p.F579L | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV64221075; called by muse, mutect2, varscan2
- PLXND1 | c.2022dup p.N675Qfs*8 | Frame Shift Ins (INS) | VAF 11/83 reads (13%) | catalogued as rs747702371; called by mutect2, varscan2
- SAXO2 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.54); catalogued as COSV59753476; called by muse, varscan2
- TTN | c.34981G>A p.V11661M (on ENST00000591111; = p.V10734M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | PolyPhen benign (0.006); catalogued as rs1371317611, COSV59909882; called by muse, varscan2
- RXFP2 | c.399G>A p.P133= | Silent (SNP) | VAF 22/337 reads (7%) | catalogued as rs767342161, COSV53633427; called by muse, mutect2
